Surgical pathology report (de-identified scan), TCGA case TCGA-50-5049, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5049-01A (Primary Tumor).

FINAL DIAGNOSIS:**Summary Statement**

The right upper lobe demonstrates a 2.8 cm invasive moderately differentiated adenocarcinoma associated with angiolymphatic and visceral pleural invasion. All sampled lymph nodes are benign. Surgical resection margins are free of tumor. Pathologic stage is T2N0MX.

**PART 1: LUNG, RIGHT UPPER LOBE, BRONCHOSCOPIC BIOPSY –
RESPIRATORY MUCOSA WITH SUBMUCOSAL SCARRING AND CHRONIC INFLAMMATION.**

**PART 2: BONE, 5TH RIB, RESECTION –
PENDING DECALCIFICATION. ADDENDUM REPORT TO FOLLOW.**

PART 3: LUNG, RIGHT UPPER LOBE, POSTERIOR SEGMENT, SEGMENTECTOMY –
A. INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA (2.8 CM IN DIAMETER) ASSOCIATED WITH
ANGIOLYMPHATIC AND VISCERAL PLEURAL INVASION. MARKED LYMPHOCYTIC HOST RESPONSE.
PATHOLOGIC STAGE: T2N0MX.
B. SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
C. BACKGROUND LUNG WITH EMPHYSEMATOUS CHANGE.

**PART 4: LYMPH NODE, LEVEL 11, BIOPSY –
THREE (3) FRAGMENTS OF BENIGN LYMPH NODE.**

**PART 5: LYMPH NODE, LEVEL 4, BIOPSY –
UNREMARKABLE FIBROADIPOSE TISSUE. NO LYMPHOID TISSUE SEEN.**

Source: NCI Genomic Data Commons file 09390da8-0289-4c9a-819f-174edbdab136 (TCGA-50-5049.3D60A219-3C2C-4E2A-AB29-5D61CD31478B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).